Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GY, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GY-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

Service:

Received:

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
LIVER CANCER.

SPECIMEN TYPE(S):
A: GALLBLADDER
B: LIVER MARGIN FS
C: RIGHT LOBE OF LIVER SEGMENT 5 & 6

FINAL DIAGNOSIS:

- A. GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis.
- B. LIVER MARGIN:
Liver parenchyma with steatosis.
No evidence of malignancy.
- C. RIGHT LOBE OF LIVER SEGMENT 5 AND 6, RESECTION:
Hepatocellular carcinoma, multifocal. (see Key Pathological Findings)
Surgical margins, free of malignancy.

Pathologic stage: pT2 NX MX.

KEY PATHOLOGICAL FINDINGS

Tumor type: Hepatocellular carcinoma, multifocal
Tumor configuration: Partially encapsulated and nodular
Tumor size: 12.5 x 7.5 x 5.0 cm and 0.8 satellite tumor nodule.
Histologic grade: Poorly differentiated
Tumor necrosis: Identified, 5%
Extent of invasion: Tumor is confined to within liver.
Perineural invasion: Not identified
Parenchymal margin: Free of malignancy
Bile duct margin: Not applicable
Venous (large vessel) invasion: Identified
Additional pathologic findings: Severe steatosis. No evidence of cirrhosis.
Lymph nodes: Not applicable
Pathologic stage: pT2 NX MX.

This case was reviewed prospectively at the

I, _____ the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

QW 4/28/14

[page 2 of 2]
NA

INTRAOPERATIVE DIAGNOSIS:

FSB: LIVER MARGIN FS:
Stenosis, Negative for tumor.

INTRADEPARTMENTAL CONSULTATION:

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
in at

C. RIGHT LOBE OF LIVER SPECIMEN 5 & 6, GROSS EXAMINATION:
Tumor present, closest margin at 0.9 cm.

I, , have performed the intraoperative
consultations and issued the above diagnoses.

GROSS DESCRIPTION:

A. Specimen A is received fresh labeled "gallbladder." The specimen consists of gallbladder which measures 9.0 x 3.0 x 2.5 cm. The serosa of the gallbladder is tan-pink, smooth, glistening. The gallbladder contents consist of a moderate amount of viscous green bile; no choleliths are grossly identified. The gallbladder wall measures 0.2 cm in thickness and is grossly unremarkable. The mucosa of the gallbladder is velvety and contains bile green. The cystic duct is patent to the flow of bile and has 0.3 cm in diameter lumen. No lymph nodes are grossly identified adjacent to gallbladder neck. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in two cassettes, A1 and A2.

B. Specimen B is received fresh, labeled "liver margin (rule out hepatoma)." The specimen consists of a single, irregular unoriented fragment of tan-red brown, soft-to-rubbery tissue, measuring 0.7 x 0.5 x 0.3 cm which is submitted entirely for frozen section as FSB.

C. Specimen C is received fresh, labeled "right lobe liver, segment 5+6." The specimen consists of 521 grams, an irregular unoriented fragment of liver parenchyma. The specimen measures 15.0 x 10.0 x 6.0 cm. The capsule of liver is tan-red brown, smooth, glistening, focally hemorrhagic. The parenchymal resection margin is grossly unremarkable and inked black. This specimen is serially sectioned to reveal an irregular to ovoid ill-defined, rubbery, intraparenchymal tumor which measures 12.5 x 7.5 x 5.0 cm. The tumor is partially adjacent, but does not appear to extend through the liver capsule, and within 0.9 cm of the closest parenchymal resection margin which is inked black. The cut surface of the tumor is homogeneous, tan-white to tan-pink, focally hemorrhagic. Also the second satellite tumor nodule is identified within the liver parenchyma, measuring up to 0.8 cm in greatest dimension. This nodule is 4.0 cm from the closest parenchymal resection margin. The remaining liver parenchyma is grossly unremarkable. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections of the specimen submitted in 9 cassettes C1-C9 as follows:

- C1-C5: Representative sections of the closest to tumor parenchymal resection margin
C6: Central part of the tumor
C7: Satellite intraparenchymal tumor nodule
C8: Tumor partially adjacent to capsule
C9: Uninvolved liver parenchyma.

Source: NCI Genomic Data Commons file 5ccd84f5-e6e3-452e-a723-54d94e932cac (TCGA-2Y-A9GY.A58D47E8-EB89-4267-830A-6EE9782D28EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).